Somatic mutation profile of tumor specimen 0DVR8E from CCDI case PBCNCF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.1 years (5,525 days).
Specimen 0DVR8E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18837fda-a28d-4f35-bc82-1830413c3527.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVR5W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4ca96fb-7b50-4871-9ed8-7946b504f882

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/282 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 110/385 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.6148G>T p.V2050F (on ENST00000358273 / NM_001042492.3; = p.V2029F on NM_000267.3) | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1300330804, COSV62223141; called by mutect2, varscan2
- TOR1AIP1 | c.1039C>G p.L347V | Missense Mutation (SNP) | VAF 139/394 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs761664196; called by muse, mutect2, varscan2
- ZSWIM9 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 79/243 reads (33%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.923); catalogued as rs1443030448; called by muse, mutect2, varscan2
- EHBP1L1 | c.2645A>G p.Q882R | Missense Mutation (SNP) | VAF 118/400 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ORM2 | c.164A>C p.Y55S | Missense Mutation (SNP) | VAF 241/642 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- CACNA1C | c.5520G>A p.L1840= | Silent (SNP) | VAF 56/209 reads (27%) | catalogued as rs1303612247; called by muse, mutect2, varscan2
- ITGA8 | c.144G>A p.V48= | Silent (SNP) | VAF 123/326 reads (38%) | called by muse, mutect2, varscan2
- TM7SF3 | c.1288-73G>T | Intron (SNP) | VAF 35/100 reads (35%) | called by muse, mutect2, varscan2
